Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3307, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3307-01A (Primary Tumor).

[page 1 of 5]
Patient Results Report

Patient Name:

MR #:

Age: Y

Sex: M

PATHOLOGY RESULTS (LABORATORY) - Changed

Results:

REPORT :

SURGICAL PATHOLOGY REPORT

* Amended *

Patient Name:

Accession :

Med. Rec. #:

Billing Type: Inpatient

Location:

DOB:

Service: Surgery

Gender: M

Billing:

Physician(s): 1

Specimen(s) Received

A: Right kidney

B: Aorto caval lymph nodes

Pathologic Diagnosis

A. Right kidney:

Histologic Type: Clear cell (conventional) renal
carcinoma

Fuhrman Grade: 3

[page 2 of 5]
[REDACTED]

Patient Results Report

Patient Name:

MR #:

Age: [REDACTED]

Sex: M

Tumor Size: Greatest dimension: 16 cm

Extent of Invasion: Tumor extends into the renal vein and
invades the perinephric fat

Margins: Renal Vein Margin uninvolved by carcinoma

Renal artery margin uninvolved by carcinoma

Ureter margin uninvolved by carcinoma

Distant Metastasis: Cannot be assessed

Specimen Type: Radical nephrectomy

Adrenal Gland: Not present

Comment: The carcinoma invades the perinephric fat at the
superior pole of the kidney. It forms a mass but per the surgeon
the adrenal was not involved and was not resected. The anterior
and posterior capsular margins are extremely close

B. Aorto caval lymph nodes: Four benign lymph nodes.

PATHOLOGIC STAGE: pT3b pN0 pMX

NOTE: Information on pathology stage and the operative procedure
is transmitted to this Institution's Cancer Registry as required
for accreditation by the Commission on Cancer. Pathology stage
is based solely upon the current tissue specimen, being
evaluated, and does not incorporate other relevant data.
Pathology stage is only a component to be considered in
determining the clinical stage, and should not be confused with
nor substituted for it. The exact operative procedure is
available in the surgeon's operative report.

Amendment comment: The mass of tumor at the superior pole of the
kidney was originally interpreted to be adrenal completely
replaced by metastatic carcinoma. The surgeon clarified that the
adrenal was not involved and not resected. The report has been

[page 3 of 5]
[REDACTED]

Patient Results Report

Patient Name: [REDACTED]

MR #:

Age: [REDACTED]

Sex: M

amended to reflect that information.

Primary Pathologist:

[REDACTED] Electronically Signed Out by: [REDACTED]

Clinical History

Right renal cell carcinoma.

Gross Description

The specimen is received fresh labeled "right kidney" and placed in formalin. It consists of a radical nephrectomy specimen covered with a mantle of tan-yellow, perirenal adipose tissue measuring 23 x 12.5 x 10 cm and weighing 1,394 grams. The surface shows prominent vasculature and is partially covered on the anterior aspect with gray-pink membranous tissue measuring 10 x 7 cm. The ureter measures 9 x 0.5 x 0.4 cm. The anterior side of the kidney is coated with black ink and the posterior side with green ink.

On bivalving the specimen, almost the entire kidney is displaced with tan-yellow hemorrhagic tumor with the exception of portions of kidney at the inferior and medial aspects. The kidney itself measures 13 x 8 x 8 cm. Tumor is identified outside the capsule at the upper pole of the kidney within the vicinity of the adrenal gland within an area measuring 5.5 x 5.5 x 4.5 cm.

Definite adrenal tissue is not grossly identified. On sectioning, the tumor abuts; however, it does not grossly extend through the capsule at the anterior and posterior aspects. No hilar lymph nodes are grossly appreciated. The tumor involves

[page 4 of 5]
[REDACTED]

Patient Results Report

Patient Name:

MR #:

Age:

Sex: M

the renal vein, however, is grossly clear of the distal margin by 1 cm. The cortex of uninvolved kidney measures up to 0.9 cm thickness. Although tumor is identified at the upper pole of the kidney within the vicinity of adrenal gland, this tumor is grossly encapsulated. Representative sections are submitted in 13 cassettes.

Block summary: "1" - distal ureter, distal renal vein and hilar vessels, "2" - tumor involving the renal vein, proximal ureter and portion of pelvis, "3" encapsulated tumor outside the upper pole of the kidney, "4-6" interface of tumor at the upper pole of the kidney and tumor within the vicinity of adrenal tissue, "7-8" - interface of uninvolved kidney and tumor, "9-10" - tumor abutting anterior capsule, "11-12" - tumor abutting posterior capsule, "13" - uninvolved kidney.

reviewed this case.

B: Received in formalin labeled "aortocaval lymph nodes". It consists of two tan yellow congested portions of fatty tissue measuring 2.3 x 1.5 x 1 cm and 5.5 x 1.9 x 1.3 cm respectively.

On sectioning both specimens, four lymph nodes are identified ranging from 1.1 to 2.1 cm in greatest dimension. The lymph nodes are totally submitted in three cassettes. Block summary: "1" - two bisected lymph nodes, "2" - one trisected lymph node, "3" - one bisected lymph node.

Microscopic Description

[REDACTED]

[page 5 of 5]
Patient Results Report

Patient Name:

MR #:

Age:

Sex: M

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Notes:

Current User:

Source: NCI Genomic Data Commons file fb225cbd-a708-4962-b325-69f62571e404 (TCGA-A3-3307.2EE79C20-487A-41B8-84F5-06FB56FC76A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).